Somatic mutation profile of tumor specimen ASCProject_0167_T2_WES (aliquot ASCProject_0167_T2_WES_1) from CMI case ASCProject_0167, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 65.6 years (23,947 days).
Specimen ASCProject_0167_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2082775e-406a-4b95-b808-68c5335eae20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0167_SALIVA (Saliva), aliquot ASCProject_0167_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d03e245-e118-4f9d-bc13-b21716d93dcf

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 3, 5'UTR 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM30 | c.1858A>T p.K620* | Nonsense Mutation (SNP) | VAF 7/69 reads (10%) | catalogued as rs1454902574, COSV65560218, COSV65560365; called by muse, mutect2
- CRAT | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548494205; called by muse, mutect2, varscan2
- METTL3 | c.1607G>A p.R536Q | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52968799; called by muse, mutect2
- RASGRF2 | c.3242C>T p.A1081V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359680355; called by muse, mutect2
- TTC21A | c.3043G>T p.E1015* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV57182976; called by muse, mutect2
- FAM124B | c.1226G>A p.S409N | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- FGF7 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- GJA1 | c.136G>T p.G46* | Nonsense Mutation (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- PARP6 | c.1237C>G p.L413V | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- PRAG1 | c.2413T>G p.S805A | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- THEMIS | c.1923A>G p.K641= | Silent (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- WFDC1 | c.555G>A p.R185= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs112023542; called by mutect2, varscan2
- ZNF326 | c.366C>T p.F122= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs142094932; called by muse, mutect2
- OFCC1 | n.1581C>A | RNA (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- RCC1 | c.-218G>T | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs755281020, COSV63120997; called by mutect2, varscan2
- RN7SL484P | chr15:99790315 A>T | 5'Flank (SNP) | VAF 5/23 reads (22%) | catalogued as rs1356638709; called by muse, mutect2, varscan2
